Somatic mutation profile of tumor specimen TCGA-4W-AA9T-01A (aliquot TCGA-4W-AA9T-01A-11D-A391-08) from TCGA case TCGA-4W-AA9T, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.2 years (19,801 days).
Specimen TCGA-4W-AA9T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efa8499c-420f-4130-8db9-5ac3145158fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4W-AA9T-10A (Blood Derived Normal), aliquot TCGA-4W-AA9T-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70bc66e7-bb86-4c9c-93ad-e8c3b91477e3

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Nonsense Mutation 4, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 318/363 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRT16 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs59856285, CM148379, CM148380, CM950726, COSV56969059, COSV56969755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.13057G>A p.A4353T | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as rs375501382; called by muse, mutect2, varscan2
- ARHGAP28 | c.1030C>T p.R344C (on ENST00000383472 / NM_001366230.1; = p.R185C on NM_001010000.3) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as rs763511946, COSV99151273; called by muse, mutect2, varscan2
- ARHGEF5 | c.2651A>G p.D884G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV50216314, COSV99283103; called by muse, mutect2, varscan2
- ATRX | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100969608; called by muse, mutect2
- AXDND1 | c.2275T>C p.S759P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs971927048, COSV100858581; called by muse, mutect2, varscan2
- BEND2 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV101192169; called by muse, mutect2, varscan2
- C17orf67 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101191013; called by muse, mutect2
- CARMIL1 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV100278592; called by muse, mutect2, varscan2
- CFAP47 | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.046); catalogued as rs372521602, COSV52892854, COSV99935568; called by muse, mutect2, varscan2
- CHD8 | c.4895C>T p.S1632L (on ENST00000646647 / NM_001170629.2; = p.S1353L on NM_020920.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100783814; called by muse, mutect2, varscan2
- COL6A3 | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781735632, COSV99800527; called by muse, mutect2, varscan2
- DOP1B | c.3203G>A p.W1068* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101215732; called by muse, mutect2, varscan2
- EEFSEC | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99631060; called by muse, mutect2, varscan2
- EXO5 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99591389; called by muse, mutect2, varscan2
- FUT5 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs200448911, COSV99398935; called by muse, mutect2, varscan2
- GREB1 | c.5740G>A p.V1914I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752664183; called by muse, mutect2, varscan2
- GRIP1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759524949, COSV54021474; called by muse, mutect2, varscan2
- KCNG4 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs780780396, COSV100377141; called by muse, mutect2, varscan2
- KCNQ2 | c.1459G>A p.G487R (on ENST00000359125 / NM_172107.4; = p.G459R on NM_004518.6) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs765301241, COSV60555910; called by muse, mutect2, varscan2
- MMP3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147533686; called by muse, mutect2, varscan2
- MYH14 | c.4822C>T p.R1608W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1249048707, COSV51833242; called by muse, mutect2
- NTM | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs145004908, COSV66205600; called by muse, mutect2, varscan2
- OR14A16 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs146819402; called by muse, mutect2, varscan2
- PAX4 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs375472849; called by muse, mutect2, varscan2
- PTEN | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as CM142084, COSV64288921, COSV64307012; called by muse, mutect2, varscan2
- RIMS1 | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs759999855, COSV53449648, COSV53465710; called by muse, mutect2, varscan2
- RP1 | c.5247A>T p.K1749N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55117766; called by muse, mutect2, varscan2
- RPL10L | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs779935712, COSV100022659; called by muse, mutect2, varscan2
- SDK1 | c.5633G>A p.R1878H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs200291743, COSV67366406; called by muse, mutect2, varscan2
- SLC5A8 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs773903392, COSV73310535; called by muse, mutect2, varscan2
- SLCO4C1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100195600; called by muse, mutect2, varscan2
- SLIT3 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100269244; called by muse, mutect2, varscan2
- TIMD4 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); catalogued as rs377724087, COSV50857541; called by muse, mutect2, varscan2
- TMEM200A | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99759797; called by muse, mutect2, varscan2
- TNRC6C | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100050526; called by muse, mutect2, varscan2
- VILL | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52184034; called by muse, mutect2, varscan2
- VLDLR | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs950640457, COSV101173238; called by muse, mutect2, varscan2
- ZBED1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100585957; called by muse, mutect2, varscan2
- ASTL | c.954_959dup p.E319_S320dup | In Frame Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, varscan2
- CYP4F11 | c.1416G>A p.A472= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1446610856, COSV56126799; called by muse, mutect2, varscan2
- EMILIN2 | c.912G>A p.P304= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs371603279; called by muse, mutect2, varscan2
- GIGYF1 | c.2139G>A p.Q713= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as rs765402186, COSV99309826; called by muse, mutect2, varscan2
- PCDHAC1 | c.2142C>T p.C714= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs561529051, COSV99168764; called by muse, mutect2, varscan2
- PHF8 | c.756C>T p.V252= (on ENST00000357988 / NM_001184896.1; = p.V216= on NM_015107.3) | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs782644934, COSV100154677; called by muse, mutect2, varscan2
- PTCD1 | c.1863C>T p.N621= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs148121169; called by muse, mutect2, varscan2
- SPNS3 | c.696C>T p.A232= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs141783753; called by muse, mutect2, varscan2
- TTN | c.96534T>C p.Y32178= (on ENST00000591111; = p.Y24754= on NM_003319.4) | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV100624777; called by muse, mutect2, varscan2
- USP29 | c.1803C>T p.A601= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs570217542, COSV99518468; called by muse, mutect2, varscan2
- ZPR1 | c.876G>A p.G292= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV99911445; called by muse, mutect2, varscan2
- LPAL2 | n.358C>A | RNA (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
